CCDI case PBCGLE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/db7b625b-43eb-4cd8-85d2-0a92594769f5

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; Tissue or organ of origin: Parotid gland; Age at diagnosis: 7.8 years (2,832 days).

Biospecimens (3 samples)
- Sample 0DRHQ2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRHQ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSBXS: Tissue type: Tumor; Specimen type: Solid Tissue.
